Gene-level copy-number profile of tumor specimen HCM-WCMC-0673-C56-05A from HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-05A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6bd0d12c-3780-4019-8c39-9f41da4b35bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0673-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/ee73a126-0648-4742-a7ce-91d99a6ffdf7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 300; copy number 2: 57,992; copy number 3: 89; copy number 4: 3; copy number 5: 3; copy number 6: 1; copy number 7: 1; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:6,924,697–6,926,076, 1 gene: DEFA6.
- chr15:23,685,400–23,687,305, 1 gene: NDN.
- chr19:39,584,042–39,598,002, 4 genes: AC011500.1, RPS29P24, RPS29P25, RPS29P26.
- chr21:44,989,864–44,995,185, 2 genes: LINC00163, LINC00165.
- chr22:18,883,502–18,884,682, 1 gene (within-gene range 0–8): AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,384,292–21,384,920, 1 gene, copy number 7: AL135744.1.
- chr22:18,773,665–18,843,399, 3 genes, copy number 5: GGT3P, AC008132.2, E2F6P1.
- chr22:18,873,543–18,894,407, 1 gene, copy number 8 (within-gene range 0–8): FAM230F.
- chr22:18,906,028–18,914,238, 1 gene, copy number 6 (within-gene range 1–6): DGCR6.

Autosomal genes at a single copy (total copy number 1): 300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
